Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7643, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7643-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS

A., B. SPECIMENS LABELED RIGHT PARIETAL NEOPLASM AND ANTERIOR CENTRAL TUMOR, REMOVAL:
-- OLIGOASTROCYTOMA (WHO GRADE II).

C. SPECIMEN LABELED POSTERIOR MARGIN, BIOPSY:
-- FRAGMENTS OF CEREBRAL CORTEX AND WHITE MATTER DEMONSTRATING FOCAL MILD
HYPERCELLULARITY.

Note: This glioma resection was diagnosed in consultation with [REDACTED]

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic diagnosis: oligoastrocytoma.

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Status: Signed Out

Addendum Diagnosis

Fluorescence In Situ Hybridization, performed at the [REDACTED] demonstrates preservation of both chromosomes 1p and 19q.

Electronically Signed Out By

Clinical History:

Right frontal tumor

Specimens Submitted As:

A:RIGHT PARIETAL NEOPLASM
B:ANTERIOR CENTRAL TUMOR
C:POSTERIOR MARGIN

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "right parietal neoplasm", are multiple pink-white soft tissue fragments, 0.8 x 0.5 x 0.4 cm in aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent.

B: Received fresh, post fixed in formalin, labeled with patient's name, number, and "A-anterior central tumor", are multiple tan-gray irregular soft tissue fragments measuring 3.0 x 2.2 x 1.6 cm in aggregate. Submitted in toto in three cassettes.

[page 2 of 2]
C: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "B-posterior margin", is one tan-gray irregular soft tissue fragment measuring 1.6 x 1.1 x 0.7 cm. On section, the fragment is tan-gray to focally red-brown. Submitted entirely in one cassette.

Summary cassettes

Specimen	Label	Site
A	1	remaining frozen tissue
	2	permanent, entirely submitted

Source: NCI Genomic Data Commons file d161e666-7dba-4a05-98b2-88219eb9db45 (TCGA-FG-7643.E6F58F35-8608-4620-B170-552A8A4FF85D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).